Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ACK4, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ACK4-TTP1-A (Primary Tumor).

[page 1 of 2]
HISTOPATHOLOGIC EXAMINATION No.

Specimen taken

Specimen received

Date of Birth:
Place of Origin:

Sex: Female

SPECIMEN(S) RECEIVED

- A) Right lower lobe of lung
- B) Lymph node, upper mediastinum
- C) Lymph node, subaortic
- D) Lymph node, subcarinal
- E) Lymph node, hilar
-

GROSS EXAMINATION

A) Specimen from atypical pulmonary resection, measuring 11.5x10 cm, with surgical staples along the margin of resection for a segment 6 cm in length. The visceral pleura appears retracted in an area 1.5 cm in diameter, where on cut section there is a neoplasm measuring 3.3 cm in greatest diameter, whitish, with scalloped margins, firm, grossly infiltrating the visceral pleura which is already sectioned and located 1.8 cm from the margin of resection. The bronchial tree shows no significant changes; the remainder of the parenchyma appears to have a spongy consistency. 4 peribronchial lymph nodes isolated.

(A1-A2 neoplasm/pleura; A3-A4 neoplasm/bronchus; A5 neoplasm/parenchyma; A6 uninvolved parenchyma; A7 bronchovascular margin of resection; A8 parenchyma margin of resection; A9 peribronchial lymph nodes).

- B) One lymph node measuring 0.5 cm in greatest diameter.
- C) One lymph node measuring 0.2 cm in greatest diameter..
- D) One lymph node measuring 0.2 cm in greatest diameter..
- E) One lymph node measuring 0.6 cm in greatest diameter..

HISTOPATHOLOGIC DIAGNOSIS

ICD-0-3
adenocarcinoma, acinar 8550/3
Site: R lung, lower lobe C34.3

ICD-10
C34.31

ju
12/16/14

[page 2 of 2]
A) Adenocarcinoma of the lung, acinar type, moderately differentiated (G2), infiltrating the visceral pleura with focal peribronchial extension. Metastases in 3 of 4 peribronchial lymph nodes. Bronchial, vascular, and parenchymal margins uninvolved.
B)C)D)E) Histiocytosis and anthracosis in the lymph nodes examined.

Staging: pT2; N1

SNOMED Coding:

T-28400 M-81403

Page 1 of 2

Continuation of report

T-C4360 M-09430
T-C4310 M-09430

Pathologist

HPV Discrepancy		/

Source: NCI Genomic Data Commons file 18c02bc5-2cd5-4f07-8b35-39c8d490f97f (CDDP-ACK4-TTP1.01A60FA5-DBDA-4078-A47A-E2F60CB05261.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).